Surgical pathology report (de-identified scan), TCGA case TCGA-EI-7002, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-7002-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 5

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Lesion excision – rectum**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis:

Examination performed on:

Macroscopic description:

A 23.6 cm length of the large intestine with mesorectum fat tissue of 2.5 cm in thickness. An ulcerous tumour sized 5.9 x 5.3 x 1.2 cm found in the mucosa. The lesion covers 100% of the intestine circumference and is located 16.4 cm away from the proximal excision line and 0.9 cm away from the distal excision line. A minimum side margin is 1.2 cm.

Microscopic description:

Adenocarcinoma tubulare (G2).

Infiltratio carcinomatosa telae adiposae mesorecti.

Excision lines clear of neoplastic infiltration.

Metastases carcinomatosae in lymphonodis (No VII / XIII).

Histopathological diagnosis:

**Adenocarcinoma tubulare recti. Tubular adenocarcinoma of the rectum.
(G2, Dukes C, Astler-Coller C2, pT3, pn2, R0).**

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 7c22fd4b-6589-4d7b-8844-0406269700d6 (TCGA-EI-7002.81A98ED7-9D11-4F7A-B648-8AF48B55074D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).